Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5GH, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5GH-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, Squamous cell
8670/3
Site: Lung, lower lobe
C34.3
JCO 2/7/13

Histopathology Report

HISTORY

SCC left lingula segment.

Lingula segmentectomy, left lower lobe lymph nodes, left hilar lymph nodes.

MACROSCOPIC

Three specimens submitted.

1. The first specimen is labelled 'left lingula lobe' and consists of a piece of lung measuring 110 x 65 x 29 mm. The visceral pleural surface is smooth and unremarkable, and does not show evidence of puckering. A stapled margin measuring 83 mm in length is identified at one edge. Serial slicing shows a solitary tumour deposit within the lung. It measures 23 x 20 x 22 mm. It is located 4 mm from the pleural surface, 20 mm from the stapled surgical resection margin, and 16 mm from the hilar resection margin. The cut surface of the tumour is firm and solid with no evidence of cavitation. The tumour appears to arise from the airways. The lung tissue distal to the tumour and remaining lung parenchyma shows no macroscopically identifiable pathology. No lymph nodes are identified. [1A, shave bronchial resection margin; 1B, shave vascular resection margin; 1C, rep TS of tumour showing its relationship to the bronchial resection margin and airways; 1D, full face of tumour; 1E-1F, rep TS of tumour showing relationship to pleural surface and lung tissue distal to the tumour. 1G, rep TS of non-neoplastic lung far away from the tumour.]

2. The second specimen is labelled 'left hilar lymph node' and consists of a fragment of brown to black tissue measuring 10 x 5 x 5 mm. [BIT, 2A.]

3. The third specimen is labelled 'left lower lobe lymph node' and consists of two fragments of black tissue measuring 6 x 6 x 5 mm and 6 x 4 x 4 mm. [BIT, 3A.]

MICROSCOPIC

1: Sections reveal a moderately differentiated squamous cell carcinoma with a central irregular zone of necrosis. The tumour crosses an apparent fissure with focal invasion of adjacent surface visceral pleura. No tumour is seen on the pleural surface. The tumour is clear of the bronchial resection margin. Focal change suspicious for perineural invasion is identified within the confines of the tumour. No unequivocal lymphatic or vascular invasion is identified. No lymph nodes are identified. Lung parenchyma immediately adjacent to the tumour shows focal change of obstructive pneumonitis. More distant lung parenchyma shows emphysema.

2&3: Sections of lymph nodes show reactive changes with sinus histiocytosis, carbon pigment deposition, scattered flecks of birefringent material in keeping with silicate and focal mild reactive follicular hyperplasia. No tumour is identified.

[page 2 of 2]
SUMMARY

1-3: Left lingula with separately submitted left hilar and left lower lobe lymph nodes:

Moderately differentiated squamous cell carcinoma.

Tumour size 23 mm.

Tumour crosses an apparent fissure with focal invasion of adjacent surface visceral pleura; no tumour seen on the pleural surface.

Bronchial resection margin clear; intraparenchymal stapled margins macroscopically clear.

Focal change suspicious for perineural invasion within confines of tumour.

No lymphatic or vascular invasion identified.

Separately submitted left hilar and left lower lobe lymph nodes not involved by tumour.

Pathological stage: pT2a N0.

Emphysema.

T-28000 M-80703 P1-03000

ANATOMICAL PATHOLOGY

Source: NCI Genomic Data Commons file 1708a774-f6eb-4826-9023-51ff75e90c12 (TCGA-77-A5GH.853CD446-E942-410E-B38D-80EA6313A405.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).